TCGA case TCGA-JW-A5VH — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: BLN - Baylor. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6813c53c-b256-4115-ad90-24d75328779e

Demographics
Sex at birth: female; Race: american indian or alaska native; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Dead; Days to death: 100 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 53.2 years (19,423 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC pathologic T: T4; AJCC pathologic N: NX; AJCC pathologic M: M1; FIGO stage: Stage IVB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 27 days; Days to treatment end: 48 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 40 days; Days to treatment end: 46 days; Treatment dose: 1,900 cGy; Treatment outcome: Progressive Disease; Number of fractions: 5; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 0 cGy; Treatment outcome: Progressive Disease; Chemo concurrent to radiation: No; Timepoint category: Postoperative; Treatment anatomic sites: Lymph Node(s) Paraaortic.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 1,900 cGy; Treatment outcome: Progressive Disease; Chemo concurrent to radiation: No; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.
   Recorded as not given: adjuvant Radiation Therapy, NOS, postoperative (reason: Adverse Event/Complications).
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Brain, NOS. Age at diagnosis: 53.4 years (19,517 days); Days to diagnosis: 94 days; Prior treatment: Yes.

Follow-up (5 entries)
- Days to follow up: 5 days; ECOG performance status: 2.
- Day 7 (preoperative): Days to imaging: 7 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Pelvic Lymph Node Involvement.
- Day 7 (preoperative): Days to imaging: 7 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 94 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 94 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 100 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 163 cm; BMI: 30.1.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-JW-A5VH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 30 mg.
  Slide TCGA-JW-A5VH-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-JW-A5VH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-JW-A5VH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 2; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 2; Tobacco smoking history indicator: 1; Days from index date to performance status: 5; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: No; Days to ct scan ab pelvis: 7; Cause of death: Cervical Cancer.
- Diagnostic ct result outcomes: Ct scan preop results: Extra-Pelvic Metastatic Disease Present; Ct scan preop results: Pelvic Nodes Present.
- Treatment, Radiation therapy info: Radiation treatment reason not completed other: Brain and Pulmonary Metastases leading to death; Radiation therapy xrt type: External beam radiation; Radiation therapy dose paraaortic nodes: 0.
- Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Not done per treating physicians discretion.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 2.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor; Cause of death: Cervical Cancer.
- Follow-up form, Treatment, Radiation therapy info: Radiation treatment reason not completed other: Deceased.
- Follow-up form, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment 2: Chemo concurrent type: Cisplatin.
- Drug treatment 1: Pharmaceutical therapy drug name: carboplatinum; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 100 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 100 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 94 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-JW-A5VH-01A-11D-A28A-01): tumor purity 0.76, ploidy 2, whole-genome doublings 0.
